Surgical pathology report (de-identified scan), TCGA case TCGA-19-5955, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-5955-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS

TCGA - 19 - 5955

A., B. RIGHT TEMPORAL LOBE OF BRAIN, TUMOR, BIOPSY AND REMOVAL:
-- GLIOBLASTOMA MULTIFORME (WHO GRADE IV).

Electronically Signed Out By

By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consultation:

A: Microscopic and touch imprint diagnosis: Glioblastoma multiforme.

Clinical History:

R brain tumor

Specimens Submitted As:

A: R TEMPORAL NEOPLASM

B: RIGHT TEMPORAL NEOPLASM

Gross Description:

A: Received fresh for intraoperative evaluation labeled with the patient's name, hospital number and "right temporal neoplasm" are two irregular fragments of white-pink soft tissue, 0.9 x 0.5 x 0.4 cm and 0.7 x 0.5 x 2.4 cm. A touch prep is performed on a portion of this tissue. A portion of this tissue is submitted for frozen section. The specimen is submitted entirely in two cassettes.

B: Received fresh, labeled with the patient's name and number, and "right temporal neoplasm", are two irregular fragments of opaque white to pink tan, soft, cerebriform tissue measuring in aggregate 2.3 x 1.9 x 0.4 cm. A portion of the specimen is submitted to [REDACTED]. The remaining tissue is submitted entirely in one cassette.

Source: NCI Genomic Data Commons file 3c44479c-049e-4d25-bdac-cbc87a964e12 (TCGA-19-5955.CC6D5233-B9DC-4551-B3BC-6B7B2B2C2C7B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).